Somatic mutation profile of cancer-model specimen HCM-CSHL-0582-C18-85M (3D Organoid, passage 5; aliquot HCM-CSHL-0582-C18-85M-01D-A82H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0582-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 56.2 years (20,518 days).
Specimen HCM-CSHL-0582-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 250cfd32-be3c-4041-b2bd-8ad381ea1814.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0582-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0582-C18-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ccd07b0-4aaa-4bdc-babc-5eb498c711e5

The open-access MAF lists 198 somatic variants for this specimen: 134 protein-altering or splice-affecting, 52 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 52, Intron 8, Nonsense Mutation 8, Frame Shift Del 3, Splice Site 3, RNA 2, Splice Region 2, In Frame Del 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4132C>T p.Q1378* | Nonsense Mutation (SNP) | VAF 440/441 reads (100%) | hotspot (GDC flag); catalogued as rs121913329, CD1110399, CM095537, COSV57322261; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 155/247 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 477/477 reads (100%) | hotspot (GDC flag); catalogued as rs876660548, CM065495, COSV52673580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM33 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 177/633 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as COSV100597856; called by muse, mutect2, varscan2
- ADGRG4 | c.7871C>T p.T2624M | Missense Mutation (SNP) | VAF 195/195 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54966971; called by muse, mutect2, varscan2
- ALB | c.814G>T p.G272* | Nonsense Mutation (SNP) | VAF 165/171 reads (96%) | catalogued as COSV55739341; called by muse, mutect2, varscan2
- ANKFN1 | c.3256G>A p.A1086T (on ENST00000653862; = p.A939T on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 369/370 reads (100%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.626); catalogued as rs1477683766, COSV73719858; called by muse, varscan2
- AP1M2 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 198/348 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs754237081, COSV51569463; called by muse, mutect2, varscan2
- AP3B2 | c.2071G>A p.A691T | Missense Mutation (SNP) | VAF 80/175 reads (46%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs765669791; called by muse, mutect2, varscan2
- APBA2 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 278/540 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs764880305, COSV68789491; called by muse, mutect2, varscan2
- ARHGAP30 | c.28_30del p.K10del | In Frame Del (DEL) | VAF 292/559 reads (52%) | catalogued as rs775704930; called by pindel, varscan2
- BAHCC1 | c.7468C>T p.P2490S | Missense Mutation (SNP) | VAF 246/246 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1158128210; called by muse, mutect2, varscan2
- CASZ1 | c.4246C>T p.R1416W | Missense Mutation (SNP) | VAF 40/557 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs772938935, COSV65456081; called by muse, mutect2
- CCDC134 | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 27/506 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs748287551; called by muse, mutect2
- CCL26 | c.186G>T p.V62= | Splice Region (SNP) | VAF 257/327 reads (79%) | catalogued as COSV50013709; called by muse, mutect2, varscan2
- CDH2 | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 44/44 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775708988, COSV52279355, COSV52293176; called by muse, varscan2
- CFAP47 | c.8137G>A p.A2713T | Missense Mutation (SNP) | VAF 69/69 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as COSV66216178; called by muse, mutect2, varscan2
- CLVS2 | c.751G>T p.G251* | Nonsense Mutation (SNP) | VAF 119/511 reads (23%) | catalogued as COSV51559397; called by muse, mutect2, varscan2
- COL4A4 | c.1543G>C p.G515R | Missense Mutation (SNP) | VAF 295/438 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100306625; called by muse, mutect2, varscan2
- DCAF12L2 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 425/425 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100758422; called by muse, mutect2, varscan2
- DLG5 | c.1880C>T p.T627M | Missense Mutation (SNP) | VAF 81/378 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.939); catalogued as rs779423863, COSV64946586; called by muse, mutect2, varscan2
- DOT1L | c.4132G>A p.G1378R | Missense Mutation (SNP) | VAF 230/854 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); catalogued as rs1415903069; called by muse, mutect2, varscan2
- DYNC1I1 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 150/583 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.286); catalogued as rs374032937; called by muse, mutect2, varscan2
- EDC4 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 147/382 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.332); catalogued as rs774004293; called by muse, mutect2, varscan2
- EFNB2 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 383/1291 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.153); catalogued as rs1187894749, COSV55366831; called by muse, mutect2, varscan2
- EFS | c.1251G>A p.Q417= | Splice Region (SNP) | VAF 122/336 reads (36%) | catalogued as COSV53731168; called by muse, mutect2, varscan2
- ENPP5 | c.1045C>A p.H349N | Missense Mutation (SNP) | VAF 41/853 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as COSV100040537; called by muse, mutect2
- EZHIP | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 148/359 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as rs782321744, COSV57956911, COSV57957472; called by muse, mutect2, varscan2
- H2BC3 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 62/120 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs1281968074; called by muse, mutect2, varscan2
- HEPHL1 | c.1972G>A p.G658R | Missense Mutation (SNP) | VAF 335/433 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs763629616; called by muse, varscan2
- HERC2 | c.13709C>T p.A4570V | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV55335915; called by muse, mutect2, varscan2
- HSH2D | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 448/651 reads (69%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs369080669; called by muse, mutect2, varscan2
- IGLV2-23 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 143/451 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs527861280; called by muse, mutect2, varscan2
- INPP1 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 26/463 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.394); catalogued as rs755770972, COSV100487250; called by muse, mutect2
- IRX1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 398/794 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57361291; called by muse, mutect2, varscan2
- KDM5A | c.1511A>G p.Y504C | Missense Mutation (SNP) | VAF 207/326 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101238638; called by muse, mutect2, varscan2
- KHSRP | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 234/397 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV101231158, COSV101231213; called by muse, mutect2, varscan2
- MMP2 | c.925G>A p.G309S | Missense Mutation (SNP) | VAF 73/680 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs949923746; called by muse, mutect2
- NAPA | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 135/348 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as rs774144496; called by muse, mutect2, varscan2
- NKAIN2 | c.62T>G p.V21G | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV100864094; called by muse, mutect2, varscan2
- NKG7 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 172/363 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765079634, COSV52467451; called by muse, mutect2, varscan2
- NPIPA1 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 165/1076 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs778271375; called by muse, mutect2, varscan2
- NYAP2 | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 103/340 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as rs200139665; called by muse, mutect2, varscan2
- OR51S1 | c.536C>A p.P179Q | Missense Mutation (SNP) | VAF 51/343 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.522); catalogued as COSV59057275; called by muse, mutect2, varscan2
- PHLPP1 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 243/244 reads (100%) | SIFT deleterious, low confidence (0.03); catalogued as rs936158178; called by muse, mutect2, varscan2
- PLEKHF2 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 70/261 reads (27%) | catalogued as COSV59541957; called by muse, mutect2, varscan2
- PLXNA2 | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 34/678 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1243245068, COSV65437353; called by muse, mutect2
- PPP1R9A | c.3167G>A p.R1056Q | Missense Mutation (SNP) | VAF 88/422 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs745926624, COSV56897461; called by muse, mutect2
- PRAMEF12 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 238/238 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs763764259; called by muse, mutect2, varscan2
- PTPRS | c.4634G>A p.R1545H | Missense Mutation (SNP) | VAF 122/414 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754177433; called by muse, varscan2
- RNF40 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 128/373 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1441685970; called by muse, mutect2, varscan2
- RTL1 | c.2692G>A p.G898S | Missense Mutation (SNP) | VAF 193/588 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as rs756553297, COSV66017006; called by muse, mutect2, varscan2
- SCART1 | c.2624G>A p.R875H | Missense Mutation (SNP) | VAF 258/693 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1043834419; called by muse, mutect2, varscan2
- SHISA9 | c.580A>G p.M194V | Missense Mutation (SNP) | VAF 20/750 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs1194295813; called by muse, mutect2
- SLITRK5 | c.1925G>A p.R642Q | Missense Mutation (SNP) | VAF 86/1503 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.053); catalogued as rs367714155, COSV61523521; called by muse, mutect2
- SMAD4 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 43/43 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61688309; called by muse, mutect2, varscan2
- STAR | c.297G>C p.E99D | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV99035368; called by muse, mutect2, varscan2
- THRB | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 129/266 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs758209560, COSV62838162; called by muse, mutect2, varscan2
- THSD7B | c.1448C>T p.T483M | Missense Mutation (SNP) | VAF 97/375 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as rs781503094, COSV55706486; called by muse, mutect2, varscan2
- TM6SF2 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 357/536 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766513047, COSV66985025; called by muse, mutect2, varscan2
- TP73 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 274/274 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756287596; called by muse, mutect2, varscan2
- UBE4A | c.1466C>G p.T489S (on ENST00000252108 / NM_001204077.2; = p.T496S on NM_004788.4) | Missense Mutation (SNP) | VAF 133/357 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs782189041; called by muse, mutect2, varscan2
- ZBTB7A | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 85/363 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs751149158, COSV100475993; called by muse, mutect2, varscan2
- ZDHHC8 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 296/463 reads (64%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.644); catalogued as rs184990183; called by muse, mutect2, varscan2
- ZNF135 | c.1744G>A p.E582K (on ENST00000313434 / NM_001289401.2; = p.E594K on NM_003436.4) | Missense Mutation (SNP) | VAF 201/409 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.413); catalogued as COSV57881387; called by muse, mutect2, varscan2
- ZNF211 | c.1208del p.G403Efs*98 (on ENST00000347302 / NM_198855.4; = p.G416Efs*98 on NM_006385.5) | Frame Shift Del (DEL) | VAF 55/386 reads (14%) | catalogued as COSV99560420; called by mutect2, pindel, varscan2
- ZNF41 | c.2203A>T p.S735C | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.639); catalogued as COSV99058131; called by muse, mutect2, varscan2
- ZNF615 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 144/348 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.029); catalogued as rs201004441, COSV100943713, COSV65034791; called by muse, mutect2, varscan2
- ZNF804A | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100170140; called by muse, mutect2, varscan2
- AARD | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 248/751 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ADGRB1 | c.1784C>G p.P595R | Missense Mutation (SNP) | VAF 131/424 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ARHGEF40 | c.3328C>A p.P1110T | Missense Mutation (SNP) | VAF 87/348 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ARID2 | c.2056C>T p.Q686* | Nonsense Mutation (SNP) | VAF 214/758 reads (28%) | called by muse, mutect2, varscan2
- BIN1 | c.711C>A p.F237L (on ENST00000316724 / NM_001320642.1; = p.F206L on NM_004305.4) | Missense Mutation (SNP) | VAF 40/489 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.627); called by muse, mutect2
- CAAP1 | c.739+1G>A p.X247_splice | Splice Site (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- CAMK2A | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 125/207 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CD180 | c.362T>G p.L121R | Missense Mutation (SNP) | VAF 52/340 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CDH15 | c.1040C>A p.P347Q | Missense Mutation (SNP) | VAF 28/632 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- CDH20 | c.731C>A p.A244D | Missense Mutation (SNP) | VAF 143/143 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFHR3 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 19/274 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.261); called by muse, mutect2
- COL4A3 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 74/770 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- CRB1 | c.3859C>T p.P1287S | Missense Mutation (SNP) | VAF 152/242 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CSMD1 | c.6193T>A p.F2065I (on ENST00000520002; = p.F2064I on NM_033225.6) | Missense Mutation (SNP) | VAF 132/132 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DCHS1 | c.4751T>G p.L1584R | Missense Mutation (SNP) | VAF 357/520 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- DCHS1 | c.4750C>G p.L1584V | Missense Mutation (SNP) | VAF 359/522 reads (69%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- DNAH7 | c.6556G>T p.V2186F | Missense Mutation (SNP) | VAF 150/254 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EFCAB8 | c.2647G>A p.D883N | Missense Mutation (SNP) | VAF 196/383 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- GNA15 | c.745-1G>T p.X249_splice | Splice Site (SNP) | VAF 19/347 reads (5%) | called by muse, mutect2
- GRM6 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- IGKV1-33 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- IQCK | c.714A>T p.Q238H | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITIH2 | c.775A>G p.R259G | Missense Mutation (SNP) | VAF 33/347 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- KIAA0825 | c.1113G>T p.K371N | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT33A | c.298T>C p.C100R | Missense Mutation (SNP) | VAF 57/384 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- LFNG | c.702C>G p.I234M (on ENST00000222725 / NM_001040167.2; = p.I105M on NM_002304.2) | Missense Mutation (SNP) | VAF 58/1132 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); called by muse, mutect2
- MAP1A | c.7516T>A p.S2506T | Missense Mutation (SNP) | VAF 141/579 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MAP3K15 | c.2092A>G p.I698V | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MASTL | c.2486T>A p.L829Q (on ENST00000375940 / NM_001372029.1; = p.L828Q on NM_032844.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/249 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MDC1 | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 57/408 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- MSL2 | c.197T>G p.V66G | Missense Mutation (SNP) | VAF 97/220 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- NAALADL2 | c.347A>T p.K116M | Missense Mutation (SNP) | VAF 24/303 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NFASC | c.815G>A p.G272E (on ENST00000339876 / NM_001378329.1; = p.G283E on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/514 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NID2 | c.2740T>A p.F914I | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOL6 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 111/321 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NPY2R | c.1052C>A p.S351Y | Missense Mutation (SNP) | VAF 263/264 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- NT5C1B | c.137A>G p.N46S | Missense Mutation (SNP) | VAF 256/366 reads (70%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NUMBL | c.609del p.K204Rfs*120 | Frame Shift Del (DEL) | VAF 56/500 reads (11%) | called by mutect2, pindel, varscan2
- NWD2 | c.3585del p.I1195Mfs*11 | Frame Shift Del (DEL) | VAF 38/317 reads (12%) | called by mutect2, pindel, varscan2
- OR2T35 | c.548C>G p.A183G | Missense Mutation (SNP) | VAF 78/701 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, varscan2
- PDZD2 | c.8027G>A p.G2676D | Missense Mutation (SNP) | VAF 291/669 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGLYRP3 | c.778A>G p.I260V | Missense Mutation (SNP) | VAF 45/735 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PLEKHN1 | c.1248C>G p.S416R (on ENST00000379409; = p.S364R on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/734 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PRX | c.1973A>G p.Q658R | Missense Mutation (SNP) | VAF 250/467 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PTPRK | c.4102G>A p.G1368R (on ENST00000368215 / NM_001291984.2; = p.G1369R on NM_002844.4) | Missense Mutation (SNP) | VAF 274/497 reads (55%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RGPD8 | c.3191T>C p.V1064A | Missense Mutation (SNP) | VAF 94/392 reads (24%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.689); called by muse, varscan2
- RNF180 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- SAMD9 | c.3562C>T p.R1188W | Missense Mutation (SNP) | VAF 74/268 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SELE | c.175C>A p.L59I | Missense Mutation (SNP) | VAF 33/588 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEMA6C | c.314G>T p.S105I | Missense Mutation (SNP) | VAF 52/829 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLC10A7 | c.593A>C p.K198T | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPIDR | c.1774-1G>A p.X592_splice | Splice Site (SNP) | VAF 64/216 reads (30%) | called by muse, varscan2
- STAT3 | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 137/314 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM132C | c.1256A>C p.E419A | Missense Mutation (SNP) | VAF 40/432 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); called by muse, mutect2
- TMEM185A | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 212/464 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMLHE | c.237C>A p.H79Q | Missense Mutation (SNP) | VAF 53/696 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2
- TPTE | c.880C>A p.H294N (on ENST00000618007 / NM_199261.4; = p.H276N on NM_199259.4) | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- TPTE | c.1052C>A p.A351D (on ENST00000618007 / NM_199261.4; = p.A333D on NM_199259.4) | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- TRAC | c.218G>T p.C73F | Missense Mutation (SNP) | VAF 79/358 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- TTC6 | c.1596G>T p.M532I | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- USP17L22 | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 146/1794 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.19); called by muse, mutect2
- VPS41 | c.702G>A p.W234* | Nonsense Mutation (SNP) | VAF 205/390 reads (53%) | called by muse, mutect2, varscan2
- WASF3 | c.1298C>A p.A433E | Missense Mutation (SNP) | VAF 50/1118 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.051); called by muse, mutect2
- ZNF703 | c.1185C>A p.S395R | Missense Mutation (SNP) | VAF 89/308 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- ZNF729 | c.367A>T p.R123* | Nonsense Mutation (SNP) | VAF 63/194 reads (32%) | called by muse, mutect2, varscan2
- ASB11 | c.897C>T p.L299= | Silent (SNP) | VAF 233/233 reads (100%) | catalogued as rs751433388, COSV100729188; called by muse, mutect2, varscan2
- BFSP1 | c.783C>T p.D261= | Silent (SNP) | VAF 226/484 reads (47%) | catalogued as rs370330055; called by muse, mutect2, varscan2
- CATSPERG | c.993C>G p.G331= | Silent (SNP) | VAF 17/229 reads (7%) | called by muse, mutect2
- CCDC168 | c.3615C>T p.V1205= | Silent (SNP) | VAF 139/632 reads (22%) | called by muse, mutect2, varscan2
- CCNA1 | c.606C>T p.G202= | Silent (SNP) | VAF 32/572 reads (6%) | called by muse, mutect2
- CDH4 | c.480C>T p.N160= | Silent (SNP) | VAF 244/1521 reads (16%) | catalogued as rs149210026; called by muse, mutect2, varscan2
- CHAC1 | c.168C>T p.F56= | Silent (SNP) | VAF 212/997 reads (21%) | catalogued as COSV71435900; called by muse, mutect2, varscan2
- CHPF2 | c.291C>T p.G97= | Silent (SNP) | VAF 44/666 reads (7%) | called by muse, mutect2
- CIT | c.4497C>T p.D1499= | Silent (SNP) | VAF 89/250 reads (36%) | catalogued as rs780669729; called by muse, mutect2, varscan2
- CLEC2A | c.429C>T p.N143= | Silent (SNP) | VAF 44/157 reads (28%) | catalogued as rs377339235; called by muse, mutect2, varscan2
- COL4A1 | c.1419C>T p.D473= | Silent (SNP) | VAF 154/1058 reads (15%) | catalogued as rs140440365, COSV65422031, COSV65423996; called by muse, mutect2, varscan2
- CRB1 | c.4197C>G p.P1399= | Silent (SNP) | VAF 158/480 reads (33%) | called by muse, mutect2, varscan2
- CRNN | c.36C>T p.I12= | Silent (SNP) | VAF 172/572 reads (30%) | catalogued as rs1394330908, COSV55121122; called by muse, mutect2, varscan2
- CTTNBP2 | c.4827T>C p.V1609= | Silent (SNP) | VAF 99/408 reads (24%) | called by muse, mutect2, varscan2
- ESR1 | c.768A>C p.R256= | Silent (SNP) | VAF 220/375 reads (59%) | called by muse, mutect2, varscan2
- FBXL7 | c.1146C>T p.N382= | Silent (SNP) | VAF 222/827 reads (27%) | catalogued as rs746695934, COSV61640788; called by muse, mutect2, varscan2
- FOXP4 | c.2002A>C p.R668= (on ENST00000307972 / NM_001012426.1; = p.R655= on NM_138457.3) | Silent (SNP) | VAF 175/799 reads (22%) | catalogued as rs1310228620; called by muse, mutect2, varscan2
- GRM2 | c.642C>T p.G214= | Silent (SNP) | VAF 171/366 reads (47%) | catalogued as rs530569899, COSV56588351; called by muse, mutect2, varscan2
- GRM7 | c.204C>T p.G68= | Silent (SNP) | VAF 262/582 reads (45%) | catalogued as COSV63130114; called by muse, mutect2
- HOXC12 | c.87C>T p.F29= | Silent (SNP) | VAF 238/419 reads (57%) | catalogued as rs762300310, COSV54535266; called by muse, mutect2, varscan2
- HSD3B2 | c.1084C>A p.R362= | Silent (SNP) | VAF 194/437 reads (44%) | catalogued as COSV65592533; called by muse, mutect2, varscan2
- IRX2 | c.1317C>T p.L439= | Silent (SNP) | VAF 107/717 reads (15%) | catalogued as rs772781529, COSV100121802; called by muse, mutect2, varscan2
- ISLR | c.198G>A p.P66= | Silent (SNP) | VAF 208/411 reads (51%) | catalogued as rs200581049; called by muse, mutect2, varscan2
- ITLN1 | c.897C>T p.S299= | Silent (SNP) | VAF 76/708 reads (11%) | called by muse, mutect2, varscan2
- KMT2B | c.5769G>A p.P1923= | Silent (SNP) | VAF 281/614 reads (46%) | catalogued as rs375845181; called by muse, mutect2, varscan2
- LRP1 | c.3702C>T p.S1234= | Silent (SNP) | VAF 192/469 reads (41%) | called by muse, mutect2, varscan2
- MANEA | c.907C>T p.L303= | Silent (SNP) | VAF 48/195 reads (25%) | called by muse, mutect2, varscan2
- MEIS1 | c.699C>T p.S233= | Silent (SNP) | VAF 230/370 reads (62%) | catalogued as rs372577277; called by muse, mutect2, varscan2
- MROH7 | c.912C>T p.S304= | Silent (SNP) | VAF 91/385 reads (24%) | called by muse, mutect2, varscan2
- PCDHA11 | c.1029C>T p.N343= | Silent (SNP) | VAF 141/452 reads (31%) | catalogued as rs371110623; called by muse, mutect2, varscan2
- PDE4D | c.399G>T p.R133= | Silent (SNP) | VAF 251/380 reads (66%) | called by muse, mutect2, varscan2
- POU3F4 | c.51A>G p.L17= | Silent (SNP) | VAF 45/318 reads (14%) | called by muse, mutect2, varscan2
- PPFIA4 | c.2742C>T p.T914= (on ENST00000447715; = p.T915= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 166/723 reads (23%) | called by muse, mutect2, varscan2
- RALGDS | c.2361C>T p.S787= | Silent (SNP) | VAF 217/699 reads (31%) | catalogued as rs774208713; called by muse, mutect2, varscan2
- REX1BD | c.405C>T p.A135= | Silent (SNP) | VAF 84/1214 reads (7%) | called by muse, mutect2
- RHPN2 | c.1359G>A p.T453= | Silent (SNP) | VAF 232/479 reads (48%) | catalogued as rs780058656; called by muse, mutect2, varscan2
- RIMBP2 | c.1275C>T p.N425= | Silent (SNP) | VAF 233/441 reads (53%) | catalogued as rs150377943, COSV55471554; called by muse, mutect2, varscan2
- SERPINA7 | c.174T>C p.T58= | Silent (SNP) | VAF 351/352 reads (100%) | catalogued as CD002711, COSV59667119; called by muse, mutect2, varscan2
- SLC12A1 | c.2256G>A p.A752= | Silent (SNP) | VAF 156/245 reads (64%) | catalogued as rs149454210; called by muse, mutect2, varscan2
- SLC38A7 | c.789C>T p.P263= | Silent (SNP) | VAF 118/322 reads (37%) | catalogued as rs1450992522; called by muse, varscan2
- SLCO6A1 | c.75G>A p.A25= | Silent (SNP) | VAF 289/479 reads (60%) | catalogued as rs1440160929, COSV65806599; called by muse, mutect2, varscan2
- SPAM1 | c.246C>T p.N82= | Silent (SNP) | VAF 114/456 reads (25%) | catalogued as rs1431798930, COSV99773193; called by muse, mutect2, varscan2
- SRFBP1 | c.687T>G p.T229= | Silent (SNP) | VAF 28/283 reads (10%) | called by muse, mutect2, varscan2
- SYNC | c.33C>T p.D11= | Silent (SNP) | VAF 396/584 reads (68%) | catalogued as rs1244605029; called by muse, mutect2, varscan2
- TBXT | c.600C>T p.N200= | Silent (SNP) | VAF 92/191 reads (48%) | catalogued as rs374566002; called by muse, mutect2, varscan2
- TENM2 | c.7986T>G p.T2662= (on ENST00000518659 / NM_001122679.2; = p.T2423= on NM_001080428.3) | Silent (SNP) | VAF 58/554 reads (10%) | called by muse, mutect2, varscan2
- TEX45 | c.18C>T p.L6= | Silent (SNP) | VAF 365/606 reads (60%) | called by muse, mutect2, varscan2
- TMEM181 | c.189C>T p.V63= | Silent (SNP) | VAF 64/361 reads (18%) | catalogued as rs772693935, COSV65562103; called by muse, mutect2, varscan2
- TNR | c.2115C>T p.I705= | Silent (SNP) | VAF 151/737 reads (20%) | called by muse, mutect2, varscan2
- VMAC | c.366T>G p.A122= | Silent (SNP) | VAF 244/725 reads (34%) | called by muse, mutect2, varscan2
- ZER1 | c.6G>A p.A2= | Silent (SNP) | VAF 157/304 reads (52%) | catalogued as rs137907314; called by muse, mutect2, varscan2
- ZNF888 | c.1944C>T p.Y648= | Silent (SNP) | VAF 107/196 reads (55%) | called by muse, mutect2, varscan2
- ASB5 | c.197-16124A>C | Intron (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
- DLGAP1 | c.958-30984T>A | Intron (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- EYS | c.1766+2591C>A | Intron (SNP) | VAF 18/180 reads (10%) | called by muse, mutect2, varscan2
- GABRG2 | c.1249-81A>T | Intron (SNP) | VAF 95/288 reads (33%) | called by muse, mutect2, varscan2
- GUK1 | c.-179C>A | 5'UTR (SNP) | VAF 134/1007 reads (13%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+3730_1999+3731dup | Intron (INS) | VAF 104/287 reads (36%) | called by mutect2, pindel, varscan2
- PCID2 | c.36+567C>T | Intron (SNP) | VAF 49/922 reads (5%) | called by muse, mutect2
- PKD1L2 | n.1325G>T | RNA (SNP) | VAF 96/227 reads (42%) | catalogued as rs1369054754; called by muse, mutect2, varscan2
- PRKCE | c.1437+210G>A | Intron (SNP) | VAF 90/359 reads (25%) | catalogued as rs1243549728; called by muse, mutect2, varscan2
- PRSS40A | n.142-2203G>A | Intron (SNP) | VAF 188/1180 reads (16%) | catalogued as rs1195177954; called by muse, mutect2, varscan2
- SILC1 | n.327G>A | RNA (SNP) | VAF 50/458 reads (11%) | called by muse, mutect2, varscan2
- SLC26A9 | c.*238T>A | 3'UTR (SNP) | VAF 68/916 reads (7%) | called by muse, mutect2
